Gene-level copy-number profile of tumor specimen TCGA-EA-A1QT-01A from TCGA case TCGA-EA-A1QT, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 47.8 years (17,475 days).
Specimen TCGA-EA-A1QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-CESC.67bf0d1f-5e2f-4340-bf1e-2ebdd583913a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EA-A1QT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/50aad3c6-ab72-4429-9a0b-a3ce3d0ccf53

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 323; copy number 2: 12,504; copy number 3: 1,945; copy number 4: 38,131; copy number 5: 3,096; copy number 6: 2,795; copy number 7: 694; copy number 8: 25; copy number 9: 1; copy number 11: 2; copy number 12: 51; copy number 15: 66; copy number 17: 6; copy number 20: 15; copy number 24: 25; copy number 27: 63; copy number 30: 9; copy number 33: 4; copy number 34: 47; copy number 41: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EA-A1QT-01A-11D-A14V-01): tumor purity 0.86, ploidy 1.86, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:5,765,076–5,856,426, 2 genes (within-gene range 0–20): ERMP1, AK4P4.
- chr20:14,933,843–15,022,958, 3 genes: AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:20,256,752–20,828,622, 9 genes: LINC02573, RNU6-772P, RN7SKP147, FDPSP6, KRT18P2, RPS3AP1, AP001506.1, LINC00320, PPIAP1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 291 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:162,486,541–162,486,949, 1 gene, copy number 24: TOMM22P6.
- chr6:65,302,522–65,789,287, 2 genes, copy number 41: AL365217.1, SLC25A51P1.
- chr6:66,710,242–66,728,904, 2 genes, copy number 12: AL450336.1, RNU7-66P.
- chr9:5,629,025–5,776,557, 2 genes, copy number 11 (within-gene range 11–20): RIC1, AL136980.1.
- chr11:66,744,451–66,977,004, 9 genes, copy number 30: C11orf80, C1QBPP2, FTLP6, RCE1, PC, LRFN4, RNU7-23P, MIR3163, C11orf86.
- chr11:68,261,338–71,252,577, 70 genes, copy number 15–33 (within-gene range 2–33) (broad region; genes not listed).
- chr21:10,328,411–17,633,199, 111 genes, copy number 12–34 (broad region; genes not listed).
- chr21:19,301,613–19,900,043, 7 genes, copy number 9–17: AP000855.1, RNU1-139P, RPL37P4, NIPA2P3, SREK1IP1P1, C1QBPP1, LINC01683.
- chr21:34,787,801–36,004,667, 1 gene, copy number 27 (within-gene range 2–27): RUNX1.
- chr21:35,472,095–38,121,345, 62 genes, copy number 27 (within-gene range 2–27) (broad region; genes not listed).
- chr21:38,380,027–39,321,559, 24 genes, copy number 24 (within-gene range 2–24): ERG, SNRPGP13, AP001037.1, LINC00114, ETS2, AP001042.1, AP001042.2, AP001042.3, AP001043.1, SNORA62, RPSAP64, LINC01700, AF064858.1, AF064858.3, AF064858.2, RPL23AP12, PCBP2P1, AF129408.2, PSMG1, BRWD1, AF129408.1, TIMM9P2, BRWD1-IT1, METTL21AP1.

Autosomal genes at a single copy (total copy number 1): 323. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
